Somatic mutation profile of tumor specimen MP2PRT-PATZNC-TMP1-A (aliquot MP2PRT-PATZNC-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATZNC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,316 days).
Specimen MP2PRT-PATZNC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eb11316-d725-49e3-b805-1d9b6d1401b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZNC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZNC-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36de8020-90dc-4fe8-acc7-4b725e018279

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 1, Silent 1, 3'Flank 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs121909673, CM011783; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 93/274 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- GNB1 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV66102222; called by muse, mutect2, varscan2
- IL7R | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 198/376 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV57406053, COSV57408353; called by muse, mutect2, varscan2
- PDZD4 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 309/347 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51247149; called by muse, mutect2, varscan2
- TMEM178B | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs576382804; called by muse, mutect2, varscan2
- CD58 | c.185_186del p.K62Sfs*8 | Frame Shift Del (DEL) | VAF 49/207 reads (24%) | called by mutect2, pindel, varscan2
- CFAP46 | c.5282A>G p.D1761G | Missense Mutation (SNP) | VAF 196/440 reads (45%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- MYH11 | c.2921_2922insTTT p.V974_T975insF | In Frame Ins (INS) | VAF 154/349 reads (44%) | called by mutect2, pindel, varscan2
- SETD1A | c.878C>A p.S293* | Nonsense Mutation (SNP) | VAF 129/298 reads (43%) | called by muse, mutect2, varscan2
- LHX3 | c.882C>T p.S294= (on ENST00000371748 / NM_178138.6; = p.S299= on NM_014564.5) | Silent (SNP) | VAF 264/822 reads (32%) | called by muse, mutect2, varscan2
- TRAJ16 | chr14:22533496 ins TGGGAT | 3'Flank (INS) | VAF 87/108 reads (81%) | called by pindel, varscan2
